Gene-level copy-number profile of tumor specimen ALCH-B3EM-TTP1-A from ALCHEMIST case ALCH-B3EM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 75.5 years (27,572 days).
Specimen ALCH-B3EM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b8519368-f05d-4ea2-8318-87b6e02ac5dc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3EM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/2c9c25a9-a327-4a75-9d96-da03540cf5ce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 229; copy number 2: 53,177; copy number 3: 4,918; copy number 4: 43; copy number 5: 1; copy number 6: 12; copy number 7: 3; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:177,438,503–177,503,647, 6 genes (within-gene range 0–2): PRR7-AS1, PRR7, DBN1, AC145098.2, PDLIM7, AC145098.1.
- chr17:61,361,668–61,485,110, 7 genes (within-gene range 0–2): AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes, copy number 7 (within-gene range 2–7): TTC34, AC242022.2, AC242022.1.
- chr16:1,240,379–1,242,554, 1 gene, copy number 10: TPSAB1.
- chr20:22,220,554–22,966,063, 13 genes, copy number 5–6: AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2, LNCNEF, LINC01747, AL158175.1, KRT18P3, CYB5AP4, AL353132.1.

Autosomal genes at a single copy (total copy number 1): 229. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
